Somatic mutation profile of tumor specimen TCGA-BJ-A4O9-01A (aliquot TCGA-BJ-A4O9-01A-11D-A257-08) from TCGA case TCGA-BJ-A4O9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 51.8 years (18,938 days).
Specimen TCGA-BJ-A4O9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8852549-7bed-4861-b660-a97eac831bec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A4O9-10A (Blood Derived Normal), aliquot TCGA-BJ-A4O9-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a671e88a-a769-4dd1-bb73-f9423ae2c73e

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AKT1 | c.399G>C p.E133D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62573317, COSV62573772; called by muse, mutect2, varscan2
- APPL1 | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55700810; called by muse, mutect2
- C2CD3 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58092961; called by muse, mutect2, varscan2
- CHD6 | c.7409A>G p.N2470S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV64690642; called by muse, mutect2, varscan2
- DPF3 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63500196; called by muse, mutect2
- ERBB4 | c.3314C>G p.S1105C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV61478337, COSV61486254; called by muse, mutect2, varscan2
- HSH2D | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53737999; called by muse, mutect2, varscan2
- MLYCD | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52305209; called by muse, mutect2, varscan2
- PDIA5 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV60249102; called by muse, mutect2, varscan2
- PLA2G2A | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425857451, COSV64287073; called by muse, mutect2, varscan2
- RAB27A | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 64/153 reads (42%) | catalogued as COSV61015721; called by muse, mutect2, varscan2
- RAD23B | c.553+1G>T p.X185_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | catalogued as COSV63658419; called by muse, mutect2, varscan2
- TRHDE | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as COSV53843941; called by muse, mutect2, varscan2
- UGT2B15 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765567860, COSV100592281; called by muse, mutect2, varscan2
- ZFX | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58446387; called by muse, mutect2, varscan2
- ZFYVE1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV59611121; called by muse, mutect2, varscan2
- FTHL17 | c.378C>T p.G126= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs779853406, COSV63266915; called by muse, mutect2, varscan2
- MPI | c.6C>T p.A2= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs149477499; called by muse, mutect2, varscan2
- OR6C75 | c.528C>T p.I176= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV58552200; called by muse, mutect2, varscan2
